Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5324, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5324-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Lymph-Node: left level 1B neck node
2. Soft Tissue: Left gingival margin - lingual side
3. Soft Tissue: Left gingival margin - labial side
4. Soft Tissue: Superior rim - Left mandible
5. Soft Tissue: Left buccal margin - [REDACTED]
6. Soft Tissue: Left soft palate margin - [REDACTED]
7. Soft Tissue: Left tongue base margin - [REDACTED]
8. Soft Tissue: Left floor of mouth - [REDACTED]
9. Soft Tissue: Left floor of mouth, Left lateral tongue and left neck contents levels 1,2,3 and 4
10. Surgical Waste

Diagnosis

1. Left level 1B neck lymph node.
One lymph node negative for tumor (0/1).
2. Left gingival margin - lingual side.
Squamous mucosa and soft tissues with chronic inflammation and reactive changes.
Negative for tumor.
3. Left gingival margin - labial side.
Squamous mucosa and soft tissues with chronic inflammation and reactive changes.
Negative for tumor.
4. Superior rim - left mandible.
Sections are in decalcification. An addendum report will follow.
5. Left buccal margin.
Squamous mucosa and soft tissues negative for tumor.
6. Left soft palate margin.
Squamous mucosa and soft tissues negative for tumor.
7. Left tongue base margin.
Squamous mucosa and soft tissues negative for tumor.
8. Left floor of mouth.
-

[page 2 of 3]
[REDACTED]

Squamous mucosa and soft tissues negative for tumor.

9. Oral cavity; left floor of mouth, left lateral tongue and left neck contents levels I, II, III, and IV.

Papillary squamous cell carcinoma, moderately differentiated.

a. Tumor maximum diameter 6.2 cm.

b. Tumor thickness 1.0 cm. Most of the thickness of tumor is the exophytic component with only superficial invasion.

c. No lymphatic/vascular invasion.

d. No perineural invasion.

e. The floor of mouth margin is positive for tumor. All the remaining margins are negative for tumor.

f. Twenty-four lymph nodes negative for tumor (0/24).

Submandibular gland with no pathologic changes.

10. "Surgical waste".

Skin and soft tissues with no pathologic changes. (Gross examination only)

[REDACTED]

Gross Description

1. The specimen is labeled with the patient's name and "left level IB neck node". It consists of portion of fibroadipose tissue measuring 1.8 x 1.1 x 0.3 in cm. One lymph node measuring 1 x 0.8 x 0.2 cm is identified.

1A one lymph node in toto

2. The specimen is labeled with the patient's name and "left gingival margin-lingual side". It consists of a piece of unoriented tissue covered by grey-white mucosa. It measures 3.3 x 1.1 x 0.4 cm. No lesion is grossly identified.

2A-2C specimen in toto

3. The specimen is labeled with the patient's name and "left gingival margin-labial side". It consists of a strip of unoriented tan-white mucosa measuring 4.3 x 0.5 x 0.2 cm. No lesion is grossly identified.

3A-3B specimen in toto

4. The specimen is labeled with the patient's name and "superior rim-left mandible". It consists of four irregular pieces of tan compact bone ranging in size from 0.5 x 0.3 x 0.1 cm to 2.4 x 1.1 x 0.4 cm. There are holes present on the larger two pieces measuring up to 0.7 cm in diameter. No gross abnormality is identified.

4A-4C submitted in toto (decalcification)

5. The specimen is labeled with the patient's name and as "left buccal margin". It consists of a fragment of tissue measuring 1.5 x 0.5 x 0.4 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "left soft palate margin". It consists of a fragment of tissue measuring 2 x 0.5 x 0.4 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and as "left tongue base margin". It consists of a fragment of tissue measuring 3.5 x 0.4 x 0.4 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "left floor of mouth". It consists of a fragment of tissue measuring 2 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and "left floor of mouth, left lateral tongue and left neck contents levels I, II, III and IV". It consists of an oriented resection of floor mouth, lateral tongue and neck contents with overall dimensions of 18.5 x 7.5 x 3.0 cm. The neck dissection includes levels I, II, III and IV and measures 12.5 x 7 x 2 cm. The

[REDACTED]

[page 3 of 3]
[REDACTED]

submandibular gland is unremarkable and measures 3.8 x 3 x 1.7 cm. Multiple lymph nodes are identified within each level ranging in size from 0.2 x 0.2 x 0.1 cm to 2.7 x 1.7 x 0.9 cm. The left lateral tongue and floor of mouth measures 6.2 x 5.2 x 2.5 cm. There is a large exophytic mass covering approximately 80% of the floor of mouth/lateral tongue surface. The tumor measures 4.8 cm SI x 6.2 cm AP. The mass is located at 0.8 cm from the closest tongue margin, extends to the mucosal margin and is at 1.0 cm from the deep soft tissue margin. Representative sections are submitted.

- 9A superior tongue with tumor
- 9B anterior tongue with tumor
- 9C inferior floor of mouth with tumor
- 9D posterior floor of mouth with tumor
- 9E tumor
- 9F submandibular gland
- 9G-9H level I two lymph nodes each
- 9I-9J level II one lymph node
- 9K-9L level II one lymph node
- 9M-9O level III one lymph node
- 9P-9Q level III multiple lymph nodes each
- 9R level IV one lymph node
- 9S-9U level IV multiple lymph nodes each

10. The specimen is labeled with the patient's name and "surgical waste". It consists of three pieces of fibroadipose tissue and muscle with skin present in two fragments. They range in size from 3.7 x 1.7 x 1.7 cm to 6.5 x 4.5 x 1.8 cm. On sectioning, no gross abnormality noted on cut surface. No tissue submitted for histologic examination.

[REDACTED]

Quick Section Diagnosis

Frozen section 5A – squamous mucosa, no carcinoma identified.
Frozen section 6A – squamous mucosa, no carcinoma identified.
Frozen section 7A – squamous mucosa, no carcinoma identified.
Frozen section 8A – squamous mucosa, no carcinoma identified.

[REDACTED]

Addendum

Addendum Diagnosis

4. Superior rim – left mandible.
Bone with reactive changes. Negative for carcinoma.

Source: NCI Genomic Data Commons file a7516907-4efd-4682-8d92-d0ff201d23c4 (TCGA-CQ-5324.E65FCE60-FC5A-40E7-A2F3-D356B672FCA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).